Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3511, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3511-01A (Primary Tumor).

Diagnosis:

Colon resectate 18 cm in length with inclusion of a 4 cm longitudinally extended, wide, ulcerated, moderately differentiated adenocarcinoma of colorectal type with wide infiltration of the pericolic fatty tissue, circumscribed penetration of the overlying serosa and evidence of lymphangiosis carcinomatosa. Tumor-free regional lymph nodes. Tumor-free colon resection margins.

Tumor stage: pT4 pN0 (0/36) pMX, G2, L1 V0

Source: NCI Genomic Data Commons file 093ae74c-710b-4d99-8473-06cfa6660477 (TCGA-AA-3511.D91B5111-C16E-4409-9381-40ABD88730A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).